Surgical pathology report (de-identified scan), TCGA case TCGA-74-6584, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Swedish Neurosciences, specimen TCGA-74-6584-01A (Primary Tumor).

[page 1 of 3]
Encounter Date: [REDACTED]

Results: PATHOLOGY / NON GYN
CYTOLOGY [REDACTED]

Status [REDACTED]

TCGA-74-6584

Collection Information

Collection Date [REDACTED]

Collection Time: [REDACTED]

Resulting Agency: [REDACTED]

Lab Information

Lab [REDACTED]

Component Results

SURGICAL PATHOLOGY REPORT

Case Number: [REDACTED]

Procedures/Addenda Present

Collected: [REDACTED]

Received: [REDACTED]

Signed Out: [REDACTED]

Reported: [REDACTED]

CLINICAL INFORMATION:

Neoplasm of unspecified nature of brain.

ICD-9 code: 239.6.

INTRAPROCEDURAL CONSULTATION:

A. Right brain tumor (frozen section): High-grade malignant neoplasm consistent with glioblastoma multiforme.

GROSS DESCRIPTION:

- A. Received fresh, labeled [REDACTED] and designated "A. right brain tumor", is a 1.0x1.0x0.2cm aggregate of pink-tan hemorrhagic soft tissue fragments. A frozen section was performed on one aspect of the tissue and is submitted in AFS. The remaining tissue was submitted in one cassette.
- B. Received fresh on [REDACTED] is approximately 30 cc of clear light orange fluid, labeled [REDACTED] B)". Prepared are one cellblock and one ThinPrep slide.
- C. Received fresh, labeled [REDACTED] and designated "C. CUSA contents", is a 6.2x3.0x1.3cm aggregate of pink-tan hemorrhagic soft tissue fragments, which are entirely submitted in three cassettes.
- D. Received in formalin, labeled [REDACTED] and designated "D. connective dura", is a 1.3x1.0x0.1cm fragment of hemorrhagic dura, which is entirely submitted in one cassette.
- E. Received fresh, labeled [REDACTED] and designated "E. right brain tumor", is a 3.5x2.5x0.9 cm aggregate of hemorrhagic pink-tan soft tissue fragments. Specimen is submitted in its entirety in two cassettes.

MICROSCOPIC DESCRIPTION:

The immunohistochemical tests reported were developed and performance characteristics determined by [REDACTED]. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests may be used for clinical purposes. They should not be regarded as investigational or for research use only. [REDACTED] is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical laboratory testing.

FINAL PATHOLOGIC DIAGNOSIS:

[page 2 of 3]
A. RIGHT BRAIN TUMOR:

C. CUSA CONTENTS:

E. RIGHT BRAIN TUMOR:

Glioblastoma, WHO grade IV/IV, with the following features:

- Degree of cellularity: High.
- Microvascular proliferation: present.
- Necrosis: present.
- Mitotic activity: high, at least 20 per 10 high power fields
- Other features: MGMT studies (PCR and immunohistochemistry) and FISH studies are pending.
- Please see comment section.

B. CYST ASPIRATE (including evaluation of cellblock):

- Proteinaceous fluid.

D. CONNECTIVE DURA:

- Fibrous connective tissue consistent with dura showing infiltrating glioblastoma.

COMMENT:

In addition to the usual features of glioblastoma, there is a region of small clustered cells in part E reminiscent of neuronal or primitive neuroectodermal differentiation. Immunostains reveal delicate synaptophysin positivity and decreased GFAP expression compared to the opposite findings in the high-grade glial component. These changes are supportive of focal primitive neuronal differentiation. P53 immunostains show staining in both components.

In part D, the glioblastoma invades the apparent dura. Foci suggestive of vascular invasion by tumor were raised and immunostains to GFAP and CD31 applied to further characterize the tumor. The tumor is GFAP positive and the dura is richly vascular. The suspected areas are not represented in the sections studied, however, and the question of vascular invasion cannot be confirmed.

Electronically Signed By

PROCEDURES/ADDENDA:

ICC- IMMUNOHISTOCHEMISTRY Date Ordered: [REDACTED] Status:

Date Complete: [REDACTED]

By: [REDACTED]

Date Reported: [REDACTED]

Interpretation

At the request of [REDACTED] representative sections of the tumor (E) were submitted for MGMT immunohistochemistry. The result is approximately 50% of the tumor is positive. Endothelial cells serve as a positive internal control.

Results-Comments

E. RIGHT BRAIN TUMOR, IMMUNOHISTOCHEMISTRY RESULTS:

-TUMOR IS POSITIVE FOR MGMT BY IMMUNOHISTOCHEMISTRY (APPROXIMATELY 50%).

[page 3 of 3]
MGMT by PCR Date Ordered:

Status:

Date Complete:

By:

Date Reported:

Interpretation
{Not Entered}

Results-Comments

E. RIGHT BRAIN TUMOR, MGMT Methylation Assay Result:
Gene Methylation NOT detected.

Please see full report from for additional details accession

[Lab Inquiry](#)

[View Complete Results](#)

Order Details

[Order Details](#)

Encounter	Hospital	Dept Phone:	Description
MRN	Encounter	Department	

Order

PATHOLOGY / NON GYN CYTOLOGY

Patient Information Patient Name Sex DOB

Admitted Date CSN

Order Information Date and Time Released By Department

Source: NCI Genomic Data Commons file 7ef7788d-0051-47a3-9fd6-2bc68142a73d (TCGA-74-6584.315CE84D-6870-4A44-BF59-E5B1BA0D94BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).